Somatic mutation profile of tumor specimen C3L-01053-01 (aliquot CPT0123860009_1) from CPTAC case C3L-01053, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 76.1 years (27,798 days).
Specimen C3L-01053-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d8ea414-4453-4222-82ae-2c9a6d9a2f92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01053-31 (Blood Derived Normal), aliquot CPT0124900002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0658a76f-62f7-4f86-9671-5b438e5ffb45

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY9 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 22/656 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.336); catalogued as rs1478370114; called by muse, mutect2
- FRMPD2 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 20/746 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as rs912294812, COSV59715128; called by muse, mutect2
- OR5H1 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 21/701 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.21); catalogued as rs1403816139; called by muse, mutect2
- PCDHGB2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.136); catalogued as COSV53970037; called by muse, mutect2
- FLNA | c.3404A>G p.N1135S | Missense Mutation (SNP) | VAF 34/971 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2
- GARNL3 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCNX1 | c.6010G>C p.D2004H | Missense Mutation (SNP) | VAF 26/796 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- OR1J1 | c.576C>T p.T192= | Silent (SNP) | VAF 26/834 reads (3%) | called by muse, mutect2
- OR5M10 | c.165G>A p.L55= | Silent (SNP) | VAF 28/1004 reads (3%) | called by muse, mutect2
- ZNF729 | c.1086C>A p.T362= | Silent (SNP) | VAF 30/662 reads (5%) | catalogued as rs1288152459; called by muse, mutect2
